Somatic mutation profile of tumor specimen HCM-SANG-0265-C18-06A (aliquot HCM-SANG-0265-C18-06A-01D-A78L-36) from HCMI case HCM-SANG-0265-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0265-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9789fc5-08a0-438f-9902-4df108c37569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0265-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0265-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a17e472b-614d-4289-a888-703319b9e12d

The open-access MAF lists 183 somatic variants for this specimen: 133 protein-altering or splice-affecting, 33 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 33, Intron 9, Nonsense Mutation 8, Splice Site 6, Frame Shift Del 6, 3'UTR 4, 5'UTR 3, Splice Region 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 93/316 reads (29%) | catalogued as rs1060503310, CD941579, CM035803, COSV57394159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 52/172 reads (30%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 219/310 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC6A1 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1396036517, COSV99822786; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 72/186 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 229/401 reads (57%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1619A>G p.Y540C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV52710061; called by muse, mutect2, varscan2
- ACAN | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs368584197, COSV61358168; called by muse, mutect2, varscan2
- ADAMTS16 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754295364, COSV57009975; called by muse, mutect2, varscan2
- ADAMTS9 | c.630C>G p.S210R | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99898767; called by muse, mutect2, varscan2
- ARHGEF37 | c.1467G>A p.P489= | Splice Region (SNP) | VAF 14/80 reads (18%) | catalogued as rs772857613; called by muse, mutect2, varscan2
- CACNA1H | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs60741169; called by muse, mutect2
- CDH6 | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 72/516 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.337); catalogued as COSV99421174; called by muse, mutect2, varscan2
- CDH9 | c.1000-1G>T p.X334_splice | Splice Site (SNP) | VAF 6/126 reads (5%) | catalogued as COSV50276196, COSV50541880, COSV99143658; called by muse, mutect2
- CLCN1 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 111/679 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58368642, COSV58369230; called by muse, mutect2, varscan2
- COL7A1 | c.5923G>A p.E1975K | Missense Mutation (SNP) | VAF 185/316 reads (59%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.709); catalogued as rs2229821; called by muse, mutect2, varscan2
- CR1L | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs1044838155; called by muse, mutect2
- CUBN | c.1201A>C p.S401R | Missense Mutation (SNP) | VAF 65/520 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1434711386; called by muse, mutect2, varscan2
- CYP17A1 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV64004706; called by muse, mutect2, varscan2
- EIF3H | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 309/550 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs200688884; called by muse, mutect2, varscan2
- EOLA2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 216/471 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.311); catalogued as rs781843529; called by muse, mutect2, varscan2
- FAM135B | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV52709678, COSV52718533; called by muse, mutect2, varscan2
- FN1 | c.5186A>C p.K1729T | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.541); catalogued as rs1278941021; called by muse, mutect2, varscan2
- HPSE2 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 90/446 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs745556418, COSV100985808, COSV65196317; called by muse, mutect2, varscan2
- IGHMBP2 | c.2265G>T p.R755S | Missense Mutation (SNP) | VAF 92/691 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446236371; called by muse, varscan2
- JAKMIP1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs745353291, COSV51547338; called by muse, mutect2, varscan2
- KATNAL1 | c.509A>C p.Q170P | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66065082; called by muse, mutect2, varscan2
- MGAT5B | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs771745922, COSV56936626; called by muse, mutect2, varscan2
- MUC15 | c.431del p.L144Rfs*15 | Frame Shift Del (DEL) | VAF 57/281 reads (20%) | catalogued as COSV55555043; called by mutect2, pindel, varscan2
- NCBP3 | c.692A>T p.D231V | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs765817847; called by muse, mutect2, varscan2
- NXPH2 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs988440643, COSV99740226; called by muse, mutect2, varscan2
- OR13C4 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV52925773; called by muse, mutect2, varscan2
- OR8B4 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.487); catalogued as rs758603752; called by muse, mutect2, varscan2
- P2RY10 | c.457A>G p.S153G | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50681608, COSV50687780; called by muse, mutect2, varscan2
- PDHA2 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs371163676; called by muse, mutect2, varscan2
- PLA2G4F | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs754233049; called by muse, mutect2, varscan2
- PLCG2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs755569519; called by muse, mutect2, varscan2
- PRSS53 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 74/341 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs371057405; called by muse, mutect2, varscan2
- RHOH | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766809804, COSV67806182; called by muse, mutect2, varscan2
- RPTN | c.1319G>A p.G440D | Missense Mutation (SNP) | VAF 154/698 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV60168890; called by mutect2, varscan2
- RSPO2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 178/388 reads (46%) | catalogued as rs773297160; called by muse, mutect2, varscan2
- SAMD9L | c.2122G>T p.D708Y | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV59081909; called by muse, mutect2, varscan2
- SCN8A | c.2832C>A p.C944* | Nonsense Mutation (SNP) | VAF 37/204 reads (18%) | catalogued as rs1555225839; called by muse, mutect2, varscan2
- SEC24C | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 70/391 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.205); catalogued as rs780721252, COSV100226674; called by muse, mutect2, varscan2
- SPDYE4 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs763254969; called by muse, mutect2, varscan2
- SYT10 | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1356281066, COSV57344622; called by muse, mutect2, varscan2
- TNS1 | c.3862C>T p.H1288Y | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.541); catalogued as COSV50705763; called by muse, mutect2
- TRIM39 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 126/601 reads (21%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.853); catalogued as rs769468484; called by muse, mutect2, varscan2
- TRO | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs776270129, COSV51497331; called by muse, mutect2, varscan2
- TTN | c.33768A>C p.K11256N (on ENST00000591111; = p.K10329N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | PolyPhen benign (0.219); catalogued as COSV100623774, COSV60186107, COSV60389020; called by muse, mutect2, varscan2
- UNC80 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 161/248 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466391695; called by muse, mutect2, varscan2
- XKR7 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs748725549, COSV73812885; called by muse, mutect2, varscan2
- ZC3H18 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs776103058; called by muse, mutect2, varscan2
- ZEB2 | c.1372A>C p.S458R | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV57960761; called by muse, mutect2, varscan2
- ZNF184 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53003216; called by muse, mutect2, varscan2
- ZNF709 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs762291246; called by muse, mutect2, varscan2
- ZZZ3 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs916523235; called by muse, mutect2, varscan2
- ADAMTS19 | c.2899T>G p.L967V | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- AKAP6 | c.1502C>A p.T501N | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF9 | c.1368_1369insC p.G457Rfs*37 | Frame Shift Ins (INS) | VAF 40/268 reads (15%) | called by mutect2, pindel, varscan2
- ARNT2 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRX | c.7298T>C p.L2433P | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ATRX | c.6776A>T p.D2259V | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- C8B | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CACNB2 | c.303_307delinsACA p.Q102Hfs*28 (on ENST00000324631 / NM_201596.3; = p.Q47Hfs*28 on NM_000724.4) | Frame Shift Del (DEL) | VAF 90/377 reads (24%) | called by pindel, varscan2*
- CDRT1 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CEMP1 | c.438G>C p.R146S | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP47 | c.7510G>C p.D2504H | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CFP | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- CHD5 | c.4912+1G>T p.X1638_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- CLPSL1 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 73/365 reads (20%) | called by muse, mutect2, varscan2
- CNBD1 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP7A1 | c.1215+1G>T p.X405_splice | Splice Site (SNP) | VAF 30/482 reads (6%) | called by muse, mutect2
- DDX21 | c.2018T>G p.V673G | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- DIAPH2 | c.3256C>A p.P1086T | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- DNAJC27 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- DNHD1 | c.13346G>A p.R4449K | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- F2RL2 | c.749A>C p.N250T | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2
- FAM124A | c.1301C>T p.P434L (on ENST00000322475 / NM_001242312.2; = p.P470L on NM_145019.4) | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- FAXDC2 | c.268T>G p.F90V | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSHR | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FUT9 | c.623A>C p.E208A | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GABBR2 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI3 | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 200/614 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- GPR158 | c.3524A>G p.E1175G | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GPR179 | c.2347G>A p.D783N (on ENST00000621958; = p.D782N on NM_001004334.4) | Missense Mutation (SNP) | VAF 145/276 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRIN2D | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR2 | c.5920G>T p.G1974C | Missense Mutation (SNP) | VAF 385/589 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KANSL1L | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KDM1B | c.1079G>T p.G360V (on ENST00000449850; = p.G228V on NM_153042.4) | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNDC1 | c.418C>G p.P140A | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LRRC31 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LVRN | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 133/464 reads (29%) | called by muse, mutect2, varscan2
- MAP4K3 | c.1195_1196del p.V399* | Frame Shift Del (DEL) | VAF 51/279 reads (18%) | called by mutect2, pindel, varscan2
- MAST4 | c.643-15_648del p.X215_splice (on ENST00000403625 / NM_001164664.2; = p.X14_splice on NM_015183.3) | Splice Site (DEL) | VAF 27/184 reads (15%) | called by mutect2, pindel, varscan2
- ME2 | c.843A>C p.Q281H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MICU3 | c.794G>T p.R265M | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NIPAL4 | c.1039G>C p.A347P | Missense Mutation (SNP) | VAF 130/973 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NKX6-1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUDT6 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACRGL | c.731G>A p.C244Y (on ENST00000471979; = p.C217Y on NM_145048.5) | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PARP1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2
- PCLO | c.4600_4601del p.G1534Lfs*5 | Frame Shift Del (DEL) | VAF 26/217 reads (12%) | called by mutect2, pindel, varscan2
- PCSK1N | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 238/617 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PLCG2 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLCXD3 | c.332_333insG p.Y111* | Nonsense Mutation (INS) | VAF 23/198 reads (12%) | called by mutect2, pindel, varscan2
- PSME3 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PTPRT | c.2144C>A p.T715N | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- SLAMF8 | c.608T>A p.V203D | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC26A8 | c.1709T>G p.L570R | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC3A1 | c.192del p.Y65Mfs*41 | Frame Shift Del (DEL) | VAF 62/369 reads (17%) | called by mutect2, pindel, varscan2
- SPART | c.1874T>G p.L625R | Missense Mutation (SNP) | VAF 99/480 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 9/47 reads (19%) | called by pindel, varscan2*
- SYNE1 | c.23763A>T p.E7921D (on ENST00000367255 / NM_182961.4; = p.E7850D on NM_033071.3) | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.957T>G p.I319M (on ENST00000367255 / NM_182961.4; = p.I326M on NM_033071.3) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TADA1 | c.692+1G>A p.X231_splice | Splice Site (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- TAF9B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TDRD15 | c.1067T>C p.L356P | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.4304A>G p.D1435G | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- THBD | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TMEM244 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TRAV8-4 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPV5 | c.1122+6T>G | Splice Region (SNP) | VAF 91/301 reads (30%) | called by muse, mutect2, varscan2
- TTC27 | c.1725A>T p.E575D | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TTN | c.22610A>G p.Q7537R (on ENST00000591111; = p.Q6610R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TUB | c.1300G>A p.D434N (on ENST00000299506 / NM_177972.3; = p.D489N on NM_003320.4) | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TUBGCP2 | c.2627G>T p.R876M | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- TUBGCP2 | c.2626A>G p.R876G | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2
- XCR1 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZFP36L2 | c.1466del p.L489Pfs*13 | Frame Shift Del (DEL) | VAF 65/388 reads (17%) | called by mutect2, pindel, varscan2
- ZNF630 | c.1285A>G p.K429E | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ZNF638 | c.2393C>A p.A798D | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF75D | c.1408A>C p.T470P | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ABCB1 | c.1611G>A p.Q537= | Silent (SNP) | VAF 92/489 reads (19%) | catalogued as rs201960151; called by muse, mutect2, varscan2
- C2orf16 | c.4326A>G p.R1442= | Silent (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- C4A | c.3573C>T p.H1191= | Silent (SNP) | VAF 202/1095 reads (18%) | catalogued as rs776084081, COSV101418309; called by muse, mutect2, varscan2
- C4BPB | c.546G>A p.G182= | Silent (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.3093C>T p.I1031= | Silent (SNP) | VAF 82/232 reads (35%) | called by muse, mutect2, varscan2
- COL11A2 | c.2076C>T p.H692= (on ENST00000341947 / NM_080680.3; = p.H585= on NM_080679.2) | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs144713192; called by muse, mutect2, varscan2
- COL4A1 | c.243T>A p.T81= | Silent (SNP) | VAF 63/401 reads (16%) | called by muse, mutect2, varscan2
- DENND3 | c.2925C>T p.S975= | Silent (SNP) | VAF 91/562 reads (16%) | called by muse, mutect2, varscan2
- FAM189A2 | c.411C>G p.P137= | Silent (SNP) | VAF 46/175 reads (26%) | called by muse, mutect2, varscan2
- FAM47C | c.489C>G p.G163= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as rs782247299; called by muse, mutect2, varscan2
- FLT4 | c.2673C>T p.R891= | Silent (SNP) | VAF 36/280 reads (13%) | catalogued as COSV56107993, COSV56110115; called by muse, mutect2, varscan2
- KIF26B | c.2436G>A p.S812= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1256029069; called by muse, mutect2, varscan2
- KLHL29 | c.165G>A p.P55= | Silent (SNP) | VAF 104/463 reads (22%) | catalogued as rs781234171, COSV72085706; called by muse, mutect2, varscan2
- KPRP | c.1260G>A p.P420= | Silent (SNP) | VAF 56/392 reads (14%) | called by muse, mutect2, varscan2
- MEIS2 | c.603A>G p.E201= (on ENST00000561208 / NM_170675.5; = p.E188= on NM_002399.3) | Silent (SNP) | VAF 7/172 reads (4%) | called by muse, mutect2
- METTL21C | c.552T>C p.A184= | Silent (SNP) | VAF 70/306 reads (23%) | called by muse, mutect2, varscan2
- NBEA | c.6612C>T p.H2204= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs369263902; called by muse, mutect2, varscan2
- NHS | c.93C>T p.S31= | Silent (SNP) | VAF 200/447 reads (45%) | called by muse, mutect2, varscan2
- NR5A1 | c.777G>A p.P259= | Silent (SNP) | VAF 81/209 reads (39%) | catalogued as rs529716231; called by muse, mutect2, varscan2
- OR6K2 | c.510G>A p.S170= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs746548556, COSV100656738, COSV62743283; called by muse, mutect2, varscan2
- PAPPA | c.2931A>G p.Q977= | Silent (SNP) | VAF 91/324 reads (28%) | catalogued as rs749773269; called by muse, mutect2, varscan2
- PCDH19 | c.858C>T p.R286= | Silent (SNP) | VAF 107/379 reads (28%) | catalogued as rs779759129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGA12 | c.1773G>C p.V591= | Silent (SNP) | VAF 218/598 reads (36%) | called by muse, mutect2, varscan2
- PDE8B | c.1512T>C p.L504= | Silent (SNP) | VAF 71/501 reads (14%) | called by muse, mutect2, varscan2
- PLPP7 | c.399G>C p.L133= | Silent (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2
- PTPRT | c.2145C>A p.T715= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- RBMXL2 | c.960C>T p.S320= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as COSV60978749; called by muse, mutect2, varscan2
- SEC14L5 | c.1788G>T p.G596= | Silent (SNP) | VAF 35/189 reads (19%) | catalogued as COSV52036564; called by muse, mutect2, varscan2
- SIGLEC7 | c.231A>G p.P77= | Silent (SNP) | VAF 15/310 reads (5%) | catalogued as rs1478213617; called by muse, mutect2
- SLAMF8 | c.609C>A p.V203= | Silent (SNP) | VAF 49/240 reads (20%) | called by muse, mutect2, varscan2
- TENM1 | c.2013T>C p.T671= | Silent (SNP) | VAF 68/702 reads (10%) | catalogued as COSV64425148, COSV64437386; called by muse, mutect2
- VCX2 | c.189G>A p.T63= | Silent (SNP) | VAF 126/520 reads (24%) | catalogued as rs770368909; called by muse, mutect2, varscan2
- WASF3 | c.690C>T p.S230= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as rs755635136, COSV58964199; called by muse, mutect2, varscan2
- ADCYAP1 | c.-46G>A | 5'UTR (SNP) | VAF 161/226 reads (71%) | called by muse, mutect2, varscan2
- ALDH6A1 | c.49-3204T>C | Intron (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- ALOX12 | c.1161+653G>A | Intron (SNP) | VAF 52/199 reads (26%) | called by muse, mutect2, varscan2
- AP2A2 | c.*660G>A | 3'UTR (SNP) | VAF 65/279 reads (23%) | catalogued as rs781676435; called by muse, mutect2, varscan2
- CPLANE1 | c.*740C>T | 3'UTR (SNP) | VAF 41/147 reads (28%) | catalogued as rs139940282; called by muse, mutect2, varscan2
- DIRC3 | n.492A>C | RNA (SNP) | VAF 7/138 reads (5%) | catalogued as COSV70404166; called by muse, mutect2
- DISC1 | c.1634+3668C>T | Intron (SNP) | VAF 46/148 reads (31%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+660G>C | Intron (SNP) | VAF 72/382 reads (19%) | called by muse, mutect2, varscan2
- HECTD3 | c.*4G>A | 3'UTR (SNP) | VAF 31/109 reads (28%) | catalogued as rs767740586; called by muse, mutect2
- NOVA1 | c.136+722A>G | Intron (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- PACRGL | c.-16-2610C>G | Intron (SNP) | VAF 54/231 reads (23%) | called by muse, mutect2, varscan2
- PAX6 | c.142-54T>A | Intron (SNP) | VAF 77/361 reads (21%) | called by muse, mutect2, varscan2
- SERPINA1 | c.-4-16dup | Intron (INS) | VAF 40/155 reads (26%) | catalogued as rs768968701; called by mutect2, varscan2
- SH3BGRL3 | c.-61C>T | 5'UTR (SNP) | VAF 98/285 reads (34%) | catalogued as rs1271261382; called by muse, mutect2, varscan2
- SYNPR | c.540+1194A>G | Intron (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- TAZ | c.*520C>T | 3'UTR (SNP) | VAF 157/666 reads (24%) | catalogued as rs1046945823; called by muse, mutect2, varscan2
- TSPAN12 | c.-47_-44dup | 5'UTR (INS) | VAF 74/440 reads (17%) | called by mutect2, pindel, varscan2
